Somatic mutation profile of tumor specimen TARGET-10-PARMIH-09A (aliquot TARGET-10-PARMIH-09A-01D) from TARGET case TARGET-10-PARMIH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,537 days).
Specimen TARGET-10-PARMIH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5206d03-a663-4553-b02f-f6731362872f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMIH-14A (Bone Marrow Normal), aliquot TARGET-10-PARMIH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19835f21-3c29-4304-8e8e-a2c66e9b7fa8

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, In Frame Ins 2, Intron 1, Frame Shift Ins 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 64/122 reads (52%) | catalogued as rs1302427305, CM021080, COSV52146014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs200709432, COSV56019223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLIPR1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767391424, COSV56989661; called by muse, mutect2, varscan2
- KRT4 | c.1256T>C p.L419P | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53410786; called by muse, mutect2, varscan2
- MYB | c.39_40insAA p.E14Kfs*39 | Frame Shift Ins (INS) | VAF 28/61 reads (46%) | catalogued as COSV57203219; called by mutect2, pindel*, varscan2*
- MYO1H | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs545577835, COSV60452543; called by muse, mutect2, varscan2
- NOTCH1 | c.4775_4776insTTCGCC p.F1592_L1593insSP | In Frame Ins (INS) | VAF 24/31 reads (77%) | catalogued as COSV53024877, COSV53028189, COSV53038773, COSV53042822, COSV53047824, COSV53049150, COSV53050117, COSV53053941, COSV53058597, COSV53059642, COSV53059832, COSV53063931, COSV53065478, COSV53068542, COSV53073834, COSV5…; called by mutect2, pindel, varscan2
- TFCP2L1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55296249; called by muse, mutect2, varscan2
- IGHV1-45 | c.349_351dup p.R117dup | In Frame Ins (INS) | VAF 44/83 reads (53%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.72G>A p.T24= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as rs1439551576; called by muse, mutect2, varscan2
- COL19A1 | c.1614G>A p.P538= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs138804129; called by muse, mutect2, varscan2
- IGHV1-45 | c.353A>C p.*118= | Silent (SNP) | VAF 44/80 reads (55%) | called by mutect2, varscan2
- SPON2 | c.456G>A p.V152= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- ATR | c.6553-29_6553-28del | Intron (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- ZNF883 | c.-67G>T | 5'UTR (SNP) | VAF 38/45 reads (84%) | called by muse, varscan2
